Somatic mutation profile of tumor specimen TCGA-MP-A4T2-01A (aliquot TCGA-MP-A4T2-01A-11D-A24P-08) from TCGA case TCGA-MP-A4T2, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 71.2 years (26,010 days).
Specimen TCGA-MP-A4T2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e74d26e-c0c8-49dc-98d8-88d28a98f662.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MP-A4T2-10A (Blood Derived Normal), aliquot TCGA-MP-A4T2-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bcb43723-260d-465f-9fe8-a9519a57b29e

The open-access MAF lists 89 somatic variants for this specimen: 66 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 20, Nonsense Mutation 8, Intron 1, Frame Shift Del 1, Splice Region 1, RNA 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.3582C>A p.F1194L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV52211220, COSV52211906, COSV99286943; called by muse, varscan2
- ACAD8 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.386); catalogued as COSV99844580; called by muse, mutect2
- AK9 | c.431T>C p.I144T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV99572804; called by muse, mutect2, varscan2
- ASNSD1 | c.913G>T p.E305* | Nonsense Mutation (SNP) | VAF 28/246 reads (11%) | catalogued as COSV99641406; called by muse, mutect2, varscan2
- BDH1 | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100827260; called by muse, mutect2, varscan2
- BRSK1 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100510975; called by muse, mutect2
- CCHCR1 | c.712G>C p.D238H | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV100885825; called by muse, mutect2, varscan2
- CDKN2AIP | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.1); catalogued as COSV100187746; called by muse, mutect2
- CFAP92 | c.509T>C p.F170S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99414970; called by muse, mutect2
- CNOT1 | c.534A>G p.I178M | Missense Mutation (SNP) | VAF 46/308 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.275); catalogued as COSV100410132; called by muse, mutect2, varscan2
- CNTN5 | c.305T>A p.V102E | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as COSV99681655; called by muse, mutect2, varscan2
- CYSLTR2 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56165168; called by muse, mutect2, varscan2
- DAPK1 | c.3649A>C p.S1217R | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.502); catalogued as COSV100802793; called by muse, mutect2, varscan2
- DNAH3 | c.8047T>A p.L2683M | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99770837; called by muse, mutect2, varscan2
- DOCK4 | c.2100G>T p.E700D | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV101447997; called by muse, mutect2
- FCN2 | c.363C>G p.I121M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99391455; called by muse, mutect2, varscan2
- HEATR1 | c.3805G>C p.D1269H | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV100857805, COSV63980491; called by muse, mutect2
- HMCN1 | c.8308A>G p.K2770E | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV99636375; called by muse, mutect2
- HMGCS1 | c.1471G>C p.E491Q | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.459); catalogued as COSV100285082; called by muse, mutect2
- INTS1 | c.2432G>T p.G811V | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as COSV101248360; called by muse, mutect2, varscan2
- LIN7C | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 9/114 reads (8%) | catalogued as rs199824050; called by muse, mutect2
- LRIT3 | c.704C>G p.P235R | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100016435; called by muse, mutect2, varscan2
- MS4A10 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.138); catalogued as rs1383022836, COSV57633047; called by muse, mutect2, varscan2
- MTMR11 | c.1905G>A p.W635* (on ENST00000439741 / NM_001145862.2; = p.W563* on NM_181873.3) | Nonsense Mutation (SNP) | VAF 9/208 reads (4%) | catalogued as rs782551257, COSV99641443; called by muse, mutect2
- MXRA5 | c.6525G>A p.W2175* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as COSV99479469; called by muse, mutect2, varscan2
- MYL9 | c.267G>T p.M89I | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99641191; called by muse, mutect2, varscan2
- NCOA5 | c.1420C>T p.Q474* | Nonsense Mutation (SNP) | VAF 6/146 reads (4%) | catalogued as COSV99276087; called by muse, mutect2
- NEDD1 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as COSV99901404; called by muse, mutect2
- NES | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV100958006; called by muse, mutect2, varscan2
- NLGN4Y | c.58A>T p.M20L | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV99946209; called by muse, mutect2, varscan2
- NLRP7 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as rs754905276, COSV100053416; called by muse, mutect2, varscan2
- NME8 | c.407T>C p.V136A | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV52253364; called by muse, mutect2
- NPBWR2 | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100871150; called by muse, mutect2, varscan2
- OR4K17 | c.633C>G p.F211L | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV100210812; called by muse, mutect2, varscan2
- PALD1 | c.2140C>T p.Q714* | Nonsense Mutation (SNP) | VAF 46/120 reads (38%) | catalogued as COSV99698687; called by muse, mutect2, varscan2
- PNPT1 | c.2123A>G p.H708R | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.444); catalogued as rs1291303562, COSV99570516; called by muse, mutect2, varscan2
- PSG11 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV60453779; called by muse, mutect2
- PSMC5 | c.508A>T p.K170* | Nonsense Mutation (SNP) | VAF 21/64 reads (33%) | catalogued as COSV99856671; called by muse, mutect2, varscan2
- RASGEF1A | c.459G>A p.E153= | Splice Region (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100988712, COSV100988734; called by muse, mutect2, varscan2
- RBM12 | c.51G>A p.M17I | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.977); catalogued as COSV58291767; called by muse, mutect2, varscan2
- RELCH | c.3350A>G p.Y1117C | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99902834; called by muse, mutect2
- RERE | c.2129G>A p.S710N | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV61951130; called by muse, mutect2, varscan2
- SENP5 | c.1671A>T p.K557N | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.929); catalogued as rs755901733, COSV100052314, COSV60207515; called by muse, mutect2, varscan2
- SETDB1 | c.1981G>T p.D661Y | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99645929; called by muse, mutect2, varscan2
- SETDB1 | c.1982A>T p.D661V | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99645931; called by muse, mutect2, varscan2
- SGSM3 | c.1442A>T p.H481L | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV99960706; called by muse, mutect2, varscan2
- SPEF1 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV101124239; called by muse, mutect2, varscan2
- SPINT2 | c.277+1G>T p.X93_splice | Splice Site (SNP) | VAF 22/73 reads (30%) | catalogued as COSV100007689; called by muse, varscan2
- SYBU | c.1438G>C p.G480R (on ENST00000276646 / NM_001099754.2; = p.G479R on NM_017786.6) | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99406681; called by muse, mutect2, varscan2
- TIAM1 | c.1171C>A p.L391M | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99739259; called by muse, mutect2
- TRBC2 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.171); catalogued as rs544245790; called by muse, mutect2, varscan2
- TRHDE | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99672732; called by muse, mutect2, varscan2
- TUBGCP6 | c.1642G>C p.A548P | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs772763001, COSV99956419; called by muse, mutect2, varscan2
- ULK4 | c.265C>G p.Q89E | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV100095436; called by muse, mutect2
- USP20 | c.1511G>A p.G504E | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV100204808; called by muse, mutect2, varscan2
- VSTM2A | c.188G>T p.W63L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV100173388; called by muse, mutect2
- WRN | c.1676C>T p.S559L | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99989967; called by muse, mutect2
- ZBTB20 | c.2122G>T p.A708S (on ENST00000474710 / NM_001164342.2; = p.A635S on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV100615362; called by muse, mutect2, varscan2
- ZFP64 | c.437G>C p.C146S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99403086; called by muse, mutect2, varscan2
- ZNF140 | c.1309C>G p.L437V | Missense Mutation (SNP) | VAF 5/106 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100166880, COSV60580112; called by muse, mutect2
- ZNF345 | c.728C>A p.S243* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | catalogued as COSV100080464, COSV59324195; called by muse, mutect2, varscan2
- ZNF407 | c.3094C>G p.L1032V | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55244296; called by muse, mutect2
- POTEE | c.2511G>T p.Q837H | Missense Mutation (SNP) | VAF 34/324 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- TRAPPC4 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.076); called by muse, mutect2
- ZEB1 | c.1748del p.S583Ffs*7 | Frame Shift Del (DEL) | VAF 15/66 reads (23%) | called by mutect2, pindel, varscan2
- ZNHIT3 | c.268C>G p.Q90E | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- ADAMTS20 | c.1809A>G p.R603= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs1216492993, COSV101240446; called by muse, mutect2, varscan2
- ARHGAP35 | c.579G>A p.K193= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as rs1477620679, COSV101351772, COSV68335118; called by muse, mutect2, varscan2
- ATP1B2 | c.363C>T p.I121= | Silent (SNP) | VAF 11/212 reads (5%) | catalogued as COSV100006974; called by muse, mutect2
- DHRS3 | c.96G>A p.K32= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV100879697; called by muse, mutect2, varscan2
- EEF1A1 | c.759C>T p.V253= | Silent (SNP) | VAF 5/100 reads (5%) | catalogued as COSV100303457; called by muse, mutect2
- GTF2E2 | c.462C>G p.L154= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV100577178; called by muse, mutect2
- HEXA | c.1257C>A p.P419= | Silent (SNP) | VAF 10/188 reads (5%) | catalogued as COSV99173855; called by muse, mutect2
- IFT81 | c.834T>A p.T278= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99656412; called by muse, varscan2
- LY75 | c.4254A>T p.A1418= | Silent (SNP) | VAF 23/82 reads (28%) | catalogued as rs752039507, COSV99717081; called by muse, mutect2, varscan2
- MEIS1 | c.834C>T p.I278= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs755601677, COSV99715844; called by muse, mutect2, varscan2
- OTOP1 | c.1497C>A p.A499= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV99588186; called by muse, mutect2, varscan2
- PAX7 | c.1374C>A p.A458= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV100946987, COSV64748724; called by muse, mutect2, varscan2
- RAP2A | c.87C>T p.I29= | Silent (SNP) | VAF 4/88 reads (5%) | catalogued as COSV55354229; called by muse, mutect2
- RNF19A | c.837T>C p.T279= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100348150; called by muse, mutect2, varscan2
- SLC17A9 | c.570C>T p.S190= | Silent (SNP) | VAF 16/166 reads (10%) | catalogued as rs774383637, COSV64847243; called by muse, mutect2
- SPEM1 | c.318G>A p.P106= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as rs200986182; called by muse, mutect2, varscan2
- SWAP70 | c.1614G>A p.V538= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100014162; called by muse, mutect2, varscan2
- TMPRSS4 | c.87C>T p.F29= | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as COSV101449434; called by muse, mutect2
- TRIM22 | c.1485A>G p.P495= | Silent (SNP) | VAF 16/127 reads (13%) | catalogued as COSV101181540; called by muse, mutect2, varscan2
- ZNF431 | c.267A>G p.Q89= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as COSV100219110; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501914 A>G | 5'Flank (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- GBA3 | c.59-8337G>A | Intron (SNP) | VAF 35/258 reads (14%) | catalogued as rs780495130; called by muse, mutect2, varscan2
- SLC22A20P | n.1536G>T | RNA (SNP) | VAF 13/84 reads (15%) | called by muse, mutect2, varscan2
